CCDI case PBBRUS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/49534cb6-4e7c-4a24-bfdc-f775c8721066

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.6 years (956 days).

Biospecimens (2 samples)
- Sample 0DFF70: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFF73: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
